Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A9V4, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A9V4-01A (Primary Tumor).

(MM/DD/YYYY)

ICD-O-3
Adenocarcinoma, mucinous
endocervical type 8482/3
Site: Cervix C53.9
J 3/7/14

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

1- "Biopsy of uterine cervix":

- Mucinous adenocarcinoma of endocervical type moderately differentiated with extensive necrosis.

Dual/Synchronous Primary	Noted	✓

Source: NCI Genomic Data Commons file 666ca720-2b8c-4e55-a28a-c56023c9286d (TCGA-VS-A9V4.6AB799DF-3327-4AFA-BE86-34C638F027CC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).